TARGET case TARGET-30-PAUMXC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56071cb7-f9f2-5e48-ba7c-8295559ee540

Demographics
Sex at birth: female; Race: white; Age at index: 3 years; Vital status: Dead; Days to death: 830 days (2.3 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C49.4; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Classification of tumor: primary; Age at diagnosis: 3.5 years (1,278 days); Year of diagnosis: 2011; Days to last follow up: 830 days (2.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 85.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ANBL0032.

Follow-up (1 entry)
- Days to follow up: 830 days (2.3 years); Days to first event: 830 days (2.3 years); First event: Death; Year of follow up: 2014.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PAUMXC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PAUMXC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 830
- Protocol: ANBL00B1, ANBL0532, ANBL0032
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
